CCDI case PBCKJC — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Spinal cord, cranial nerves, and other parts of central nervous system.
https://portal.gdc.cancer.gov/cases/1cd616f7-659e-4fe2-bb38-917f677780e9

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Myxopapillary ependymoma: ICD-O-3 morphology code: 9394/1; Tissue or organ of origin: Spinal cord; Age at diagnosis: 19.1 years (6,973 days).

Biospecimens (3 samples)
- Sample 0DU3KH: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DU3LJ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DU3ML: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
